Gene-level copy-number profile of tumor specimen TCGA-OR-A5KY-01A from TCGA case TCGA-OR-A5KY, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 23.9 years (8,745 days).
Specimen TCGA-OR-A5KY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.ce287f91-80f7-4187-ae42-c85b4d67ff07.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5KY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-OR-A5KY-01A|TCGA-OR-A5KY-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/54e4f931-676f-471d-91c1-5a7eaec0c1af

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,028; copy number 2: 35,481; copy number 3: 10,928; copy number 4: 4,311; copy number 5: 6,072.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5KY-01A-11D-A29H-01): tumor purity 0.74, ploidy 2.46, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,072 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:28,307,063–28,751,722, 12 genes, copy number 5: AC093690.1, RPL23AP34, FLJ31356, FOSL2, AC104695.3, AC104695.2, AC104695.1, PLB1, SNRPGP7, AC074011.1, RNA5SP89, AC092164.1.
- chr9:14,475–138,203,325, 2,322 genes, copy number 5 (broad region; genes not listed).
- chr12:66,767–92,531,324, 2,049 genes, copy number 5 (broad region; genes not listed).
- chr19:18,204,730–18,607,741, 29 genes, copy number 5 (within-gene range 4–5): AC005759.1, AC008397.2, PDE4C, AC008397.1, IQCN, JUND, MIR3188, RPL39P38, LSM4, RN7SL513P, PGPEP1, GDF15, MIR3189, LRRC25, SSBP4, ISYNA1, AC010335.1, ELL, AC010335.2, AC010335.3, AC005387.1, FKBP8, AC005387.2, KXD1, AC005253.1, AC005253.2, UBA52, CRLF1, REX1BD.
- chr19:28,790,812–58,605,223, 1,660 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 607. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
